Gene-level copy-number profile of specimen HCM-SANG-1300-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1300-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1300-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9f6bc510-84ef-4545-a609-4357caa90d64.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1300-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/dcc8e70c-5a55-485a-95fd-b354b1641119

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 2,096; copy number 2: 12,445; copy number 3: 36,592; copy number 4: 3,825; copy number 5: 1,708; copy number 6: 1,819; copy number 7: 367; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,257,411–49,472,085, 2 genes (within-gene range 0–2): AGBL4-AS1, AGBL4-IT1.
- chr4:187,746,094–189,984,871, 33 genes: ADAM20P3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P.
- chr17:18,426,861–18,494,945, 7 genes: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 369 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:52,488,993–52,587,095, 2 genes, copy number 8 (within-gene range 6–8): AL137058.1, AL137058.3.
- chr20:48,624,252–64,327,972, 366 genes, copy number 7 (broad region; genes not listed).
- chr21:24,306,939–24,547,942, 1 gene, copy number 7 (within-gene range 1–7): LINC01684.

Autosomal genes at a single copy (total copy number 1): 1,591. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
